Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3D6, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3D6-01A (Primary Tumor).

[page 1 of 2]
Redacted Case Pathology Report

DOB: _____ Sex: F
Physician: _____

Received: _____

Accession: _____

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to _____, the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) SUPERIOR LARYNGEAL NERVE, BIOPSY:
Nerve twig and connective tissue; no tumor present.
- (B) NODULE CRICO-THYROID MEMBRANE:
METASTATIC PAPILLARY THYROID CARCINOMA WITH PSAMMOMA BODIES INVOLVING CONNECTIVE TISSUE.
- (C) TOTAL THYROIDECTOMY:
PAPILLARY THYROID CARCINOMA INVOLVING LEFT LOBE OF THYROID GLAND WITH EXTENSION THROUGH THYROID CAPSULE INTO PERI-THYROIDAL CONNECTIVE TISSUE; TUMOR IS PRESENT AT THE POSTERIOR SOFT TISSUE RESECTION MARGIN. (SEE COMMENT)
Thyroid isthmus, no tumor present.
Right lobe of thyroid gland, no tumor present.
Two unremarkable left parathyroid glands.
- (D) THYROID NODULE:
One lymph node, no tumor present.
- (E) SECTION CODE NOT UTILIZED.
- (F) RIGHT PARATRACHEAL NODULE:
One lymph node and connective tissue; no tumor present.
- (G) LEFT PARATRACHEAL AND SUPERIOR MEDIASTINAL TISSUE:
METASTATIC PAPILLARY THYROID CARCINOMA INVOLVING 1 OF 1 LYMPH NODE.
- (H) LEVEL III LYMPH NODES:
Three lymph nodes, no tumor present.
- (I) "INTRA-THYROID LYMPH NODE":
Small nerve twigs, connective tissue and skeletal muscle, no tumor present.

1CB-0-3

carcinoma papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

10/15/11

Entire report and diagnosis completed by: _____
Rec'd released by: _____

GROSS DESCRIPTION

- (A) SUPERIOR LARYNGEAL NERVE - One soft, irregular pink-tan fragment (0.6 x 0.3 x 0.2 cm). Entirely submitted for frozen section.
*FS/DX: NERVE AND CONNECTIVE TISSUE; NO TUMOR PRESENT.
- (B) NODULE, CRICOTHYROID MEMBRANE - An irregular fragment of tissue measuring 0.3 x 0.3 x 0.2 cm. Entirely submitted for frozen section in B.
*FS/DX: PROBABLE METASTATIC PAPILLARY THYROID CARCINOMA WITH PSAMMOMA BODIES INVOLVING CONNECTIVE TISSUE; QUESTION PROGRESSION ONTO MORE AGGRESSIVE FORM OF THYROID CARCINOMA.

Page 1 of 2

History Case Pathology Report
File under: Pathology

History Case Pathology

[page 2 of 2]
History Case Pathology Report

Department of Pathology,

DOB:
Physician

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

(C) TOTAL THYROIDECTOMY - A total thyroidectomy specimen consists of: the tumor-distorted left lobe of thyroid gland (approximately 6 x 4.7 x 3.2 cm); attached unremarkable isthmus (1.5 x 0.6 x 0.4 cm); and attached unremarkable right lobe of thyroid gland.

The left thyroid lobe is replaced and expanded by tumor which forms a relatively well-defined globular, firm and partially cystic mass that is approximately 5.5 x 4.5 x 3 cm. The mass is light gray to light pink with extensive fibrosis and friable papillary protrusions. A rim of apparently normal thyroid is present. No gross extension of tumor outside the fibrous surrounding the mass.

SECTION CODE:

C01-C20, tumor and normal thyroid gland.

(D) LEFT THYROID NODULE - A single portion of tan, red, soft tissue measuring 0.3 cm in total dimension. Submitted in toto for further examination as D.

*FS/DX: ONE LYMPH NODE AND CONNECTIVE TISSUE; NO TUMOR PRESENT.

(E) Section code not utilized.

(F) RIGHT PARATRACHEAL NODULE - A single portion of tan, soft tissue (0.4 x 0.4 x 0.2 cm); submitted in toto for frozen section examination as F.

*FS/DX: PARATHYROID GLAND, NO TUMOR PRESENT.

(G) LEFT PARATRACHEAL AND SUPERIOR MEDIASTINAL TISSUE FOR PERMANENT - One ovoid, tan nodule (1 x 0.5 x 0.5 cm) with scanty, attached yellow-tan adipose tissue. The node is dissected and entirely submitted in G.

(H) LEFT LEVEL III - Three ovoid tan lymph nodes ranging from 0.4 to 1.2 cm in greatest dimension with attached adipose tissue.

SECTION CODE:

H1 - two lymph nodes;

H2, H3 - one lymph node, bisected.

(I) INTRATHYROID LYMPH NODE FOR PERMANENT - An ovoid fragment of tan, soft tissue 0.5 x 0.3 x 0.3 cm with scanty attached adipose tissue; entirely submitted in I.

CONSULTATION

SNOMED CODES

Source: NCI Genomic Data Commons file 3fbdc29c-7b41-4aae-83ed-63e6e1db02e7 (TCGA-EL-A3D6.A4EA7225-4DF5-4917-A931-B41DF5F7FA31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).